Somatic mutation profile of tumor specimen TCGA-CJ-4912-01A (aliquot TCGA-CJ-4912-01A-01D-1429-08) from TCGA case TCGA-CJ-4912, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 61.9 years (22,623 days).
Specimen TCGA-CJ-4912-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2831cc90-9303-4d70-a783-eec930bcc9be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4912-11A (Solid Tissue Normal), aliquot TCGA-CJ-4912-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48da5424-ee29-4014-bad4-272c83b989e1

The open-access MAF lists 89 somatic variants for this specimen: 69 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Nonsense Mutation 7, Frame Shift Del 5, In Frame Del 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG4 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 48/175 reads (27%) | catalogued as rs267606777, CM061705, COSV57389289; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTG1 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59509914; called by muse, mutect2
- ADGRA1 | c.1288C>G p.P430A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV66925146; called by muse, mutect2
- ADGRE3 | c.920G>A p.W307* | Nonsense Mutation (SNP) | VAF 46/142 reads (32%) | catalogued as COSV53728781; called by muse, mutect2, varscan2
- ADRB2 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60005280; called by muse, mutect2
- AKAP7 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53833953; called by muse, mutect2, varscan2
- ARID1A | c.6824T>C p.I2275T | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV61373809; called by muse, varscan2
- BANK1 | c.193T>A p.F65I | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.114); catalogued as COSV59839970; called by muse, mutect2, varscan2
- BCAR3 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as COSV53073234; called by muse, mutect2, varscan2
- CLSTN1 | c.691C>A p.H231N (on ENST00000377298 / NM_001009566.3; = p.H221N on NM_014944.4) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV63647053; called by muse, mutect2, varscan2
- COL1A2 | c.2299C>A p.P767T | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV51954855, COSV51965209; called by muse, mutect2, varscan2
- CSMD2 | c.6916G>A p.V2306I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs143826784; called by muse, mutect2, varscan2
- CUL1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 19/136 reads (14%) | catalogued as COSV57387480; called by muse, mutect2, varscan2
- EMILIN1 | c.2538G>C p.E846D | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV53153837; called by muse, mutect2, varscan2
- FAM83B | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1341059482, COSV60920265; called by muse, mutect2, varscan2
- FOXM1 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61205497; called by muse, mutect2, varscan2
- FYB1 | c.973C>G p.P325A | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV100685873, COSV60942857; called by muse, mutect2
- GBF1 | c.2438G>C p.C813S (on ENST00000369983 / NM_001377137.1; = p.C812S on NM_004193.3) | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.055); catalogued as COSV64143565; called by muse, mutect2, varscan2
- GGN | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53056335; called by muse, mutect2, varscan2
- IPO11 | c.1019A>C p.E340A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV57573310; called by muse, mutect2, varscan2
- KCNH7 | c.3070A>C p.S1024R | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.273); catalogued as COSV59790291; called by muse, mutect2, varscan2
- KLHL21 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV66553078; called by muse, mutect2, varscan2
- LMTK2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 166/240 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1439045018, COSV51992419; called by muse, mutect2, varscan2
- LRTM2 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as rs775644958, COSV54564694; called by muse, mutect2, varscan2
- MCCC2 | c.1373G>A p.S458N | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.25); catalogued as COSV60153163; called by muse, mutect2, varscan2
- MPZL2 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV54048440; called by muse, mutect2, varscan2
- MROH2B | c.281A>C p.E94A | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68182196; called by muse, mutect2, varscan2
- MTFR2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV63078776, COSV63078916; called by muse, mutect2, varscan2
- MYBL1 | c.1680G>T p.K560N | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72918803, COSV72919262; called by muse, mutect2, varscan2
- MYO10 | c.2012C>G p.A671G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV57018409; called by muse, mutect2, varscan2
- NOTCH2 | c.4229G>A p.R1410H | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs202022988, COSV56685752; called by muse, varscan2
- NRROS | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs766225300, COSV60745053; called by muse, mutect2, varscan2
- NSD1 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV61772543; called by muse, mutect2, varscan2
- NUP160 | c.2559T>G p.N853K | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.321); catalogued as COSV65853852; called by muse, mutect2, varscan2
- PBRM1 | c.2977_2980del p.L993Mfs*20 | Frame Shift Del (DEL) | VAF 53/97 reads (55%) | catalogued as COSV56266470; called by mutect2, pindel, varscan2
- PLAGL2 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55787763; called by muse, mutect2, varscan2
- PRTFDC1 | c.425A>C p.D142A | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.924); catalogued as COSV60773532; called by muse, mutect2, varscan2
- RAD50 | c.1870A>G p.S624G | Missense Mutation (SNP) | VAF 139/273 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV54748977; called by muse, mutect2, varscan2
- RBM26 | c.1056T>G p.I352M | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.168); catalogued as COSV57392472; called by muse, mutect2, varscan2
- RBM28 | c.1513A>T p.K505* | Nonsense Mutation (SNP) | VAF 25/157 reads (16%) | catalogued as COSV56162052; called by muse, mutect2, varscan2
- RC3H1 | c.1574T>C p.I525T | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs766861260, COSV51198534; called by muse, mutect2, varscan2
- SEC23IP | c.194G>C p.S65T | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64830993; called by muse, mutect2, varscan2
- SEL1L2 | c.1572A>C p.K524N | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.444); catalogued as COSV53149356; called by muse, mutect2
- SLC14A2 | c.538G>T p.G180* | Nonsense Mutation (SNP) | VAF 50/178 reads (28%) | catalogued as COSV54907270; called by muse, mutect2, varscan2
- SLC9A1 | c.377C>G p.S126* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV56052064, COSV56056480; called by muse, mutect2, varscan2
- SYCP2L | c.758G>C p.W253S | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51651340; called by muse, mutect2, varscan2
- TAFA4 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs267599929, COSV55135149; called by muse, mutect2, varscan2
- TBC1D24 | c.1294G>A p.V432M (on ENST00000646147 / NM_001199107.2; = p.V426M on NM_020705.3) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53545566; called by muse, mutect2, varscan2
- TNIK | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52676764; called by muse, mutect2, varscan2
- TNRC6B | c.2069A>C p.K690T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV57291230; called by muse, mutect2, varscan2
- TSHZ3 | c.3079A>G p.K1027E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53666855; called by muse, mutect2, varscan2
- TTN | c.78655G>C p.V26219L (on ENST00000591111; = p.V18795L on NM_003319.4) | Missense Mutation (SNP) | VAF 38/127 reads (30%) | PolyPhen benign (0.05); catalogued as COSV59939967; called by muse, mutect2, varscan2
- UBN2 | c.839A>G p.K280R | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV56028725; called by muse, mutect2, varscan2
- WDR93 | c.1382T>A p.I461N | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV51531131; called by muse, mutect2, varscan2
- WNK1 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 79/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60027818, COSV60032261; called by muse, mutect2, varscan2
- ZDHHC5 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54705651; called by muse, mutect2, varscan2
- ZNF215 | c.308A>C p.E103A | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53492160; called by muse, mutect2, varscan2
- ZNF292 | c.5822A>C p.Q1941P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as COSV60536837; called by muse, mutect2, varscan2
- ZNF429 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV61915067; called by muse, mutect2, varscan2
- ZNF543 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV58626743; called by muse, mutect2
- ZNF560 | c.1548T>G p.F516L | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV56866556; called by muse, mutect2, varscan2
- ZNF713 | c.1076G>A p.C359Y (on ENST00000633730 / NM_001366796.2; = p.C372Y on NM_182633.3) | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185738884, COSV70056503; called by muse, mutect2, varscan2
- ACOT1 | c.886del p.L296* | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- CAMK1 | c.51_62del p.R17_D21delinsS | In Frame Del (DEL) | VAF 65/137 reads (47%) | called by mutect2, pindel, varscan2
- NBPF20 | c.16728del p.E5576Dfs*54 (on ENST00000369373; = p.E5137Dfs*54 on NM_001278267.1) | Frame Shift Del (DEL) | VAF 112/463 reads (24%) | called by mutect2, pindel, varscan2
- RMND5B | c.876del p.C292Wfs*7 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- SHANK2 | c.2342_2343insTCCAAGC p.S782Pfs*7 | Frame Shift Ins (INS) | VAF 12/86 reads (14%) | called by mutect2, varscan2*
- SPNS2 | c.1015_1023del p.Y339_H341del | In Frame Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel
- VHL | c.349del p.W117Gfs*42 | Frame Shift Del (DEL) | VAF 140/289 reads (48%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.5448T>C p.I1816= | Silent (SNP) | VAF 53/288 reads (18%) | catalogued as rs1237941570, COSV51581554; called by muse, mutect2, varscan2
- BCAR3 | c.1119C>A p.A373= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV53073254; called by muse, mutect2, varscan2
- BDH2 | c.711C>A p.V237= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV56477933; called by muse, mutect2, varscan2
- CCDC157 | c.744C>G p.P248= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV57838019; called by muse, mutect2, varscan2
- DUSP16 | c.1767T>A p.T589= | Silent (SNP) | VAF 51/277 reads (18%) | catalogued as COSV53806764; called by muse, mutect2, varscan2
- GPBAR1 | c.198G>T p.L66= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV50307048; called by muse, mutect2, varscan2
- IGF2R | c.2676C>T p.V892= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV63627174; called by muse, mutect2, varscan2
- IGFLR1 | c.519G>A p.L173= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as rs755229649, COSV53074129; called by muse, mutect2, varscan2
- KANK1 | c.3129T>C p.T1043= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as rs758462957, COSV63209835, COSV63210109; called by muse, mutect2, varscan2
- KMT2A | c.6138T>A p.P2046= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as COSV63283396; called by muse, mutect2, varscan2
- MAOA | c.453A>G p.K151= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV58641675, COSV58645485; called by muse, mutect2, varscan2
- RABGAP1 | c.1684T>C p.L562= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV65392278; called by muse, mutect2, varscan2
- RNASEL | c.2190T>C p.A730= | Silent (SNP) | VAF 77/258 reads (30%) | catalogued as rs1405039428, COSV62376405; called by muse, mutect2, varscan2
- RNPEPL1 | c.1260C>T p.V420= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV54372143; called by muse, mutect2, varscan2
- SLC5A12 | c.1008T>C p.L336= | Silent (SNP) | VAF 54/206 reads (26%) | catalogued as COSV54819942; called by muse, mutect2
- SVOPL | c.654C>A p.A218= (on ENST00000419765; = p.A66= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV55989257; called by muse, mutect2, varscan2
- TRPC4 | c.1071G>A p.L357= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs1239017401, COSV58993807, COSV59018387; called by muse, mutect2, varscan2
- WDFY3 | c.6024C>T p.Y2008= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as rs1279253579, COSV55695860; called by muse, mutect2, varscan2
- ZMYM1 | c.2577C>A p.V859= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV63251029; called by muse, mutect2, varscan2
- TLCD2 | chr17:1713912 C>A | 5'Flank (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
